Somatic mutation profile of tumor specimen TCGA-4Z-AA7O-01A (aliquot TCGA-4Z-AA7O-01A-31D-A391-08) from TCGA case TCGA-4Z-AA7O, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 64.7 years (23,645 days).
Specimen TCGA-4Z-AA7O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b935c146-efc2-48bb-9aa4-cb7e05655b7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4Z-AA7O-10A (Blood Derived Normal), aliquot TCGA-4Z-AA7O-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dc4557a-f7db-409d-8fea-e810d35abe17

The open-access MAF lists 215 somatic variants for this specimen: 150 protein-altering or splice-affecting, 55 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 55, Nonsense Mutation 13, Intron 6, Splice Site 4, Frame Shift Del 3, Splice Region 2, 5'UTR 1, 5'Flank 1, Frame Shift Ins 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1435C>G p.R479G (on ENST00000281708 / NM_001349798.2; = p.R399G on NM_018315.5) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747241612, COSV55894141, COSV55894999, COSV55908957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.3761A>T p.Q1254L (on ENST00000404938 / NM_001163941.2; = p.Q809L on NM_178559.6) | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1284676591, COSV51703384; called by muse, mutect2, varscan2
- ACSBG1 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 132/348 reads (38%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs534659934, COSV51903374; called by muse, mutect2, varscan2
- ADAM17 | c.1258C>G p.L420V | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV60397602; called by muse, mutect2, varscan2
- ADAMTS9 | c.4228C>G p.Q1410E | Missense Mutation (SNP) | VAF 82/225 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV55775491; called by muse, mutect2, varscan2
- AKAP6 | c.1199C>G p.T400S | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV55205901; called by muse, mutect2, varscan2
- AKAP6 | c.2007G>A p.W669* | Nonsense Mutation (SNP) | VAF 34/74 reads (46%) | catalogued as COSV99805244; called by muse, mutect2, varscan2
- ALDH18A1 | c.1608G>A p.V536= | Splice Region (SNP) | VAF 56/128 reads (44%) | catalogued as COSV64662128; called by muse, mutect2, varscan2
- ALG13 | c.2990A>G p.Y997C | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV52635491; called by muse, mutect2, varscan2
- ANK2 | c.2744A>G p.Y915C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV52147575; called by muse, mutect2, varscan2
- ANXA7 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV65822973; called by muse, mutect2, varscan2
- APOH | c.338+1G>A p.X113_splice | Splice Site (SNP) | VAF 24/48 reads (50%) | catalogued as rs138141538; called by muse, mutect2, varscan2
- ARHGAP9 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.58); catalogued as rs1406234187, COSV62721410; called by muse, mutect2, varscan2
- ARID1A | c.3634C>T p.Q1212* | Nonsense Mutation (SNP) | VAF 39/69 reads (57%) | catalogued as COSV61372355, COSV61372574; called by muse, mutect2, varscan2
- AZU1 | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); catalogued as rs747759846, COSV52140167; called by muse, mutect2, varscan2
- BRINP3 | c.1229G>T p.C410F | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1191081025, COSV66514429, COSV66535381; called by muse, mutect2, varscan2
- BTBD2 | c.887G>T p.R296L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV55307592; called by muse, varscan2
- CACHD1 | c.272A>G p.K91R | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.08); catalogued as COSV51548763; called by muse, mutect2, varscan2
- CARF | c.541A>G p.K181E | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.438); catalogued as COSV57546607; called by muse, mutect2, varscan2
- CCDC116 | c.1287C>A p.N429K | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV53039436, COSV99489458; called by muse, mutect2, varscan2
- CCDC158 | c.1186G>T p.E396* | Nonsense Mutation (SNP) | VAF 34/94 reads (36%) | catalogued as COSV101187424; called by muse, mutect2, varscan2
- CCDC82 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.012); catalogued as COSV53592269; called by muse, mutect2, varscan2
- CDH9 | c.34T>C p.W12R | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV50253421; called by muse, mutect2, varscan2
- CEACAM1 | c.1247-1G>C p.X416_splice | Splice Site (SNP) | VAF 25/57 reads (44%) | catalogued as COSV50725556; called by muse, mutect2, varscan2
- CES3 | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as COSV57592730; called by muse, mutect2, varscan2
- CFHR2 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs753517273, COSV66380522; called by muse, mutect2, varscan2
- CIT | c.1360A>G p.K454E | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1477680093, COSV55860858; called by muse, mutect2, varscan2
- CKM | c.774G>T p.Q258H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as COSV53461727; called by muse, mutect2, varscan2
- CLEC4G | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.766); catalogued as rs773992274, COSV61002864; called by muse, varscan2
- CLUAP1 | c.1040G>C p.R347T | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV58892713; called by muse, mutect2, varscan2
- COA1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.04); catalogued as rs780227085, COSV56240475; called by muse, mutect2, varscan2
- DSPP | c.553C>G p.Q185E | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as COSV56808212; called by muse, mutect2, varscan2
- EDEM3 | c.633C>G p.I211M | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.87); PolyPhen benign (0.026); catalogued as COSV58922073; called by muse, mutect2, varscan2
- ELAPOR1 | c.2210A>G p.Y737C | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64039990; called by muse, mutect2, varscan2
- EPG5 | c.5824G>A p.E1942K | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.736); catalogued as COSV56344978; called by muse, mutect2, varscan2
- ETV6 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56765454; called by muse, mutect2, varscan2
- EVI5L | c.1807G>C p.E603Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); catalogued as COSV54483945, COSV99563589; called by muse, mutect2, varscan2
- FARS2 | c.707T>G p.V236G | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV51164695; called by muse, mutect2, varscan2
- FBXO42 | c.1948G>A p.D650N | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.762); catalogued as rs765433001, COSV65044553, COSV65045219; called by muse, mutect2, varscan2
- FNBP4 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 57/79 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV55446277, COSV55446535; called by muse, mutect2, varscan2
- GLOD4 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1271259672, COSV56752534; called by muse, mutect2, varscan2
- GPR101 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 46/59 reads (78%) | SIFT tolerated (0.28); PolyPhen benign (0.334); catalogued as COSV53237543; called by muse, mutect2, varscan2
- GUCY2C | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV53787045; called by muse, mutect2, varscan2
- GUCY2C | c.2081G>C p.R694T | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV53787060; called by muse, mutect2, varscan2
- H4C5 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63486199; called by muse, mutect2, varscan2
- HEATR3 | c.1957C>T p.Q653* | Nonsense Mutation (SNP) | VAF 40/101 reads (40%) | catalogued as COSV53530844; called by muse, mutect2, varscan2
- HERC1 | c.9749G>A p.R3250Q | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs377471691; called by muse, varscan2
- HNF1A | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as rs368683806, CM1310932, CM993760; called by muse, mutect2, varscan2
- IGHMBP2 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 64/346 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54820237; called by muse, mutect2, varscan2
- IKZF2 | c.488C>A p.S163Y | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV59576512, COSV59576736; called by muse, mutect2, varscan2
- IL18BP | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as COSV52619916; called by muse, mutect2, varscan2
- ITPRID1 | c.1495G>A p.V499I | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV60070525; called by muse, mutect2, varscan2
- JAZF1 | c.624C>G p.F208L | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV52233122; called by muse, mutect2, varscan2
- JDP2 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.148); catalogued as rs767203503, COSV50867807; called by muse, mutect2, varscan2
- KATNA1 | c.282G>C p.E94D | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59501475; called by muse, mutect2, varscan2
- KCNJ4 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs1475409490, COSV57856227; called by muse, mutect2, varscan2
- KIAA1549 | c.1088C>G p.S363* | Nonsense Mutation (SNP) | VAF 46/117 reads (39%) | catalogued as COSV54314230; called by muse, mutect2, varscan2
- KIF1C | c.2741C>T p.P914L | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs779132007, COSV57903052; called by muse, mutect2, varscan2
- KIFC1 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766822322, COSV65728590; called by muse, mutect2, varscan2
- KMT2D | c.10321C>T p.Q3441* | Nonsense Mutation (SNP) | VAF 35/83 reads (42%) | catalogued as COSV56427390; called by muse, mutect2, varscan2
- KRTAP21-2 | c.242C>G p.S81C | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); catalogued as rs750056609, COSV61683898; called by muse, mutect2, varscan2
- LDB2 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.896); catalogued as rs142034467, COSV100455011; called by muse, mutect2, varscan2
- LGR6 | c.855G>A p.T285= (on ENST00000367278 / NM_001017403.1; = p.T233= on NM_021636.3) | Splice Region (SNP) | VAF 12/108 reads (11%) | catalogued as rs749687454, COSV55151967, COSV99707686; called by muse, mutect2, varscan2
- LTBP1 | c.874C>G p.L292V | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs768903642, COSV63180644; called by muse, mutect2, varscan2
- MACC1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs754530577, COSV60540999, COSV60545195; called by muse, mutect2, varscan2
- MAGEB6B | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 35/46 reads (76%) | catalogued as COSV69689585; called by muse, mutect2, varscan2
- MBD5 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.578); catalogued as COSV68695837; called by muse, mutect2, varscan2
- MBD5 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV68695841; called by muse, mutect2, varscan2
- MCCC1 | c.521G>C p.G174A | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV55606552; called by muse, mutect2, varscan2
- MDK | c.144C>A p.S48R | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs1416385913, COSV100552127; called by muse, mutect2, varscan2
- MFSD6L | c.1622T>A p.I541K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as rs759219955, COSV61687451; called by muse, mutect2, varscan2
- MPPE1 | c.375G>T p.K125N | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV57881734; called by muse, mutect2, varscan2
- MRPL55 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs775022732, COSV54341846; called by muse, mutect2, varscan2
- MTHFD1L | c.424G>C p.D142H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.77); catalogued as COSV66208182; called by muse, mutect2, varscan2
- MTMR7 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV51663241; called by muse, mutect2, varscan2
- MYBPC1 | c.2546A>G p.Y849C (on ENST00000550270 / NM_206820.2; = p.Y856C on NM_002465.4) | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs780287009, COSV62251217; called by muse, mutect2, varscan2
- MYCL | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs775579460, COSV65693042; called by muse, mutect2, varscan2
- MYH6 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1271657601, COSV62448081; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH8 | c.507G>C p.L169F | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV67960234; called by muse, mutect2, varscan2
- MYO3A | c.1367A>G p.N456S | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56320712; called by muse, mutect2, varscan2
- NADSYN1 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 95/192 reads (49%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.612); catalogued as COSV59810343; called by muse, mutect2, varscan2
- OAS3 | c.1351C>T p.H451Y | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763532611, COSV57444265; called by muse, mutect2, varscan2
- OR2W3 | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs139324473; called by muse, mutect2, varscan2
- OR3A2 | c.785G>C p.G262A | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.392); catalogued as COSV68694940, COSV68695332; called by muse, mutect2, varscan2
- OR4D6 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1348344333, COSV55659012; called by muse, mutect2, varscan2
- OR8I2 | c.142T>G p.L48V | Missense Mutation (SNP) | VAF 92/206 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.061); catalogued as COSV56166729; called by muse, mutect2, varscan2
- OSBP2 | c.1634A>G p.N545S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as rs201627938, COSV60239932; called by muse, mutect2, varscan2
- PACS2 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1555410545, COSV57650184; called by muse, mutect2, varscan2
- PAX7 | c.1214C>A p.S405Y | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs1331383105, COSV64748637; called by muse, mutect2, varscan2
- PCDHGA5 | c.2018C>A p.A673D | Missense Mutation (SNP) | VAF 145/201 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as rs374896827; called by muse, mutect2, varscan2
- PCK1 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs747438321, COSV60126288; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCNX1 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 49/105 reads (47%) | catalogued as COSV99457634; called by muse, mutect2, varscan2
- PHLDA1 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as COSV56997869, COSV99876736; called by muse, mutect2, varscan2
- PLAU | c.513G>C p.K171N | Missense Mutation (SNP) | VAF 109/274 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV65640831; called by muse, mutect2, varscan2
- PLCH1 | c.4501G>C p.E1501Q (on ENST00000340059 / NM_001130960.2; = p.E1493Q on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58187761; called by muse, mutect2, varscan2
- PLD2 | c.2623C>G p.L875V | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV54003678; called by muse, mutect2, varscan2
- POLG | c.2406G>T p.R802S | Missense Mutation (SNP) | VAF 68/197 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51519762; called by muse, mutect2, varscan2
- POM121L12 | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV68692287; called by muse, mutect2, varscan2
- PRKDC | c.6406C>T p.P2136S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.078); catalogued as rs1356862227, COSV100043441; called by muse, mutect2, varscan2
- PROX1 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as rs896925287, COSV54776196, COSV54779311; called by muse, mutect2, varscan2
- PRPF6 | c.1406C>G p.T469R | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV53866068; called by muse, mutect2, varscan2
- PRSS12 | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56604331; called by muse, mutect2, varscan2
- PSD3 | c.2110C>T p.Q704* (on ENST00000440756; = p.Q703* on NM_015310.4) | Nonsense Mutation (SNP) | VAF 47/120 reads (39%) | catalogued as COSV99677090; called by muse, varscan2
- RAB6C | c.426G>C p.E142D | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.019); catalogued as COSV69339298; called by muse, mutect2, varscan2
- RHOB | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV55355253; called by muse, mutect2, varscan2
- RYR1 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62089230; called by muse, mutect2, varscan2
- RYR2 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as rs939164326, COSV63664393; called by muse, mutect2, varscan2
- SEL1L2 | c.1123C>T p.H375Y | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as rs760998207, COSV53148331; called by muse, mutect2, varscan2
- SLC27A6 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52479640; called by muse, mutect2, varscan2
- SLC4A11 | c.2624G>A p.R875Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as rs751709036, COSV66260568; called by muse, mutect2, varscan2
- SLC5A10 | c.1097G>A p.R366Q (on ENST00000395645 / NM_001042450.4; = p.R382Q on NM_152351.5) | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs745820799, COSV58755483; called by muse, mutect2, varscan2
- SLIT2 | c.2894C>T p.P965L | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs374116662; called by muse, mutect2, varscan2
- SMARCC2 | c.400-1G>A p.X134_splice | Splice Site (SNP) | VAF 14/86 reads (16%) | catalogued as COSV57214484; called by muse, mutect2, varscan2
- SPECC1L | c.2509C>G p.P837A | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV58656646; called by muse, mutect2, varscan2
- SPHKAP | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV60869481; called by muse, mutect2, varscan2
- SSH3 | c.1131T>G p.N377K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV57383439; called by muse, mutect2, varscan2
- STPG4 | c.19G>C p.A7P | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.023); catalogued as COSV54277891, COSV54278016; called by muse, mutect2, varscan2
- SUCO | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 131/236 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV55262255; called by muse, mutect2, varscan2
- SYNE1 | c.14797G>C p.E4933Q (on ENST00000367255 / NM_182961.4; = p.E4862Q on NM_033071.3) | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); catalogued as COSV54914325, COSV99037646; called by muse, mutect2, varscan2
- SYNE1 | c.2986G>A p.G996R (on ENST00000367255 / NM_182961.4; = p.G1003R on NM_033071.3) | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV54914363; called by muse, mutect2, varscan2
- TBL1X | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV54275250; called by muse, mutect2, varscan2
- TENM3 | c.4727G>C p.R1576P | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.989); catalogued as COSV69299915; called by muse, mutect2, varscan2
- TIMM10B | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 18/32 reads (56%) | catalogued as COSV99601719; called by muse, mutect2, varscan2
- TMCO4 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150663799, COSV53869337; called by muse, mutect2, varscan2
- TMEM132B | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV54745574; called by muse, mutect2, varscan2
- TMPRSS11D | c.1034del p.G345Efs*28 | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | catalogued as COSV52222771; called by mutect2, pindel, varscan2
- TNN | c.2753G>A p.R918H | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.993); catalogued as rs61746976, COSV53422028; called by muse, mutect2, varscan2
- TP53BP1 | c.4906C>T p.P1636S | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.958); catalogued as COSV55496726; called by muse, mutect2, varscan2
- TRH | c.613C>G p.Q205E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV57014605; called by muse, mutect2, varscan2
- TRPC5 | c.1301G>T p.W434L | Missense Mutation (SNP) | VAF 52/65 reads (80%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.854); catalogued as COSV53284814; called by muse, mutect2, varscan2
- TRPS1 | c.2740G>A p.G914R (on ENST00000220888 / NM_001330599.2; = p.G927R on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1563716999, COSV55227817, COSV55246629; called by muse, mutect2, varscan2
- TTN | c.83545G>C p.E27849Q (on ENST00000591111; = p.E20425Q on NM_003319.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | PolyPhen benign (0.295); catalogued as COSV59902451; called by muse, mutect2, varscan2
- TUBGCP2 | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as rs773975087, COSV53305009; called by muse, mutect2, varscan2
- USP28 | c.359del p.G120Efs*45 | Frame Shift Del (DEL) | VAF 39/81 reads (48%) | catalogued as COSV99036241; called by mutect2, pindel, varscan2
- UST | c.217C>G p.R73G | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1443900449, COSV100820253, COSV66545773; called by muse, mutect2, varscan2
- UTRN | c.7646G>T p.S2549I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs1404441378, COSV62306049; called by muse, mutect2, varscan2
- VCAN | c.8482C>T p.P2828S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as COSV99426141; called by muse, mutect2
- VPS33A | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.194); catalogued as rs373704049; called by muse, mutect2, varscan2
- VWA7 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs373092700, COSV63304540; called by muse, mutect2, varscan2
- ZFAND1 | c.56-1G>C p.X19_splice | Splice Site (SNP) | VAF 30/95 reads (32%) | catalogued as COSV55106736; called by muse, mutect2, varscan2
- ZMPSTE24 | c.678C>A p.F226L | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs1392832079, COSV65638747; called by muse, mutect2, varscan2
- ZNF385B | c.203C>G p.S68C | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.57); catalogued as COSV69800806; called by muse, mutect2, varscan2
- ZNF43 | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); catalogued as COSV100731933, COSV61682855, COSV61684299; called by muse, mutect2, varscan2
- ZNF607 | c.427C>G p.Q143E | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67696225; called by muse, mutect2, varscan2
- AQP6 | c.421dup p.T141Nfs*174 | Frame Shift Ins (INS) | VAF 55/141 reads (39%) | called by mutect2, pindel, varscan2
- FOXD4L5 | c.990A>T p.L330F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.049); called by mutect2, varscan2
- HIRA | c.1813C>T p.R605* | Nonsense Mutation (SNP) | VAF 5/103 reads (5%) | called by muse, mutect2
- KMT2D | c.2783_2793dup p.P932Sfs*2 | Nonsense Mutation (INS) | VAF 18/56 reads (32%) | called by mutect2, varscan2
- SPTAN1 | c.1210del p.Q404Kfs*35 | Frame Shift Del (DEL) | VAF 27/44 reads (61%) | called by mutect2, pindel, varscan2
- TRAV25 | c.53A>G p.N18S | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANAPC1 | c.1572A>G p.T524= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as rs753530824, COSV61974330, COSV61975254; called by muse, mutect2, varscan2
- ASCC2 | c.1471C>T p.L491= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs1284473626, COSV57072087; called by muse, mutect2, varscan2
- ASIC3 | c.1488C>T p.T496= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs367609780; called by muse, mutect2, varscan2
- CACNA1E | c.1941C>T p.I647= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs1250744066, COSV62383279; called by muse, mutect2, varscan2
- CAMK2B | c.1881C>T p.D627= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs1463275169, COSV51657646, COSV51660743; called by muse, mutect2, varscan2
- CD200R1L | c.213G>C p.L71= | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as COSV101236665; called by muse, mutect2
- CDC20 | c.915G>A p.L305= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as COSV60521707; called by muse, mutect2, varscan2
- CDK6 | c.591C>T p.A197= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV56005215; called by muse, mutect2, varscan2
- CHD5 | c.2316G>A p.A772= | Silent (SNP) | VAF 65/85 reads (76%) | catalogued as rs1256483251, COSV52408272; called by muse, mutect2, varscan2
- CNBD1 | c.552C>T p.S184= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs774522037, COSV101575269, COSV72975911; called by muse, mutect2, varscan2
- COMMD4 | c.288G>A p.L96= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV51190189; called by muse, mutect2, varscan2
- CSTF2T | c.741G>T p.V247= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV58656007; called by muse, mutect2, varscan2
- DMBX1 | c.378C>T p.F126= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV63601687; called by muse, mutect2, varscan2
- EGLN2 | c.546C>T p.I182= | Silent (SNP) | VAF 67/182 reads (37%) | catalogued as rs373843220; called by muse, mutect2, varscan2
- EPPK1 | c.5187C>T p.F1729= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as rs781920013, COSV73260850; called by muse, mutect2, varscan2
- EVI5L | c.1806G>A p.A602= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs1180851747, COSV54483930, COSV99563031; called by muse, mutect2, varscan2
- FARP1 | c.2661G>A p.Q887= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV60330789; called by muse, mutect2, varscan2
- FBXO28 | c.786C>T p.T262= | Silent (SNP) | VAF 43/142 reads (30%) | catalogued as COSV64799718; called by muse, mutect2, varscan2
- FZD1 | c.615C>T p.F205= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs757876150, COSV55309088, COSV55309195, COSV55311290; called by muse, mutect2, varscan2
- GCKR | c.1368C>T p.I456= | Silent (SNP) | VAF 92/240 reads (38%) | catalogued as rs386352306, COSV53106611; ClinVar: uncertain significance; called by muse, varscan2
- GFAP | c.1014C>T p.L338= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV53649077; called by muse, mutect2, varscan2
- GGPS1 | c.156G>C p.V52= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV51396901; called by muse, mutect2, varscan2
- GINS4 | c.42G>T p.G14= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV52530869; called by muse, mutect2, varscan2
- HMCN1 | c.6639C>T p.L2213= | Silent (SNP) | VAF 52/180 reads (29%) | catalogued as COSV54879474; called by muse, mutect2, varscan2
- IGKV2D-24 | c.189G>A p.Q63= | Silent (SNP) | VAF 48/172 reads (28%) | called by muse, mutect2, varscan2
- INPPL1 | c.1344G>C p.S448= | Silent (SNP) | VAF 34/243 reads (14%) | catalogued as COSV53353465, COSV53355260; called by muse, mutect2, varscan2
- KAT6B | c.189C>T p.V63= | Silent (SNP) | VAF 36/113 reads (32%) | catalogued as COSV54742597; called by muse, mutect2, varscan2
- LARP4B | c.1014G>A p.A338= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as rs1056498691, COSV60220081; called by muse, mutect2, varscan2
- LRSAM1 | c.1977G>A p.V659= | Silent (SNP) | VAF 23/28 reads (82%) | catalogued as rs1190478414, COSV55938448; called by muse, mutect2, varscan2
- MROH5 | c.928C>T p.L310= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV101436100, COSV71300541; called by muse, mutect2, varscan2
- MTG1 | c.477C>A p.L159= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV58152915, COSV58155089; called by muse, mutect2, varscan2
- MYOF | c.828G>C p.L276= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as COSV63700557; called by muse, mutect2
- NFATC2 | c.102C>T p.F34= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs774757283, COSV65353349; called by muse, mutect2, varscan2
- PCDHA13 | c.183G>A p.P61= | Silent (SNP) | VAF 44/70 reads (63%) | catalogued as COSV56493090; called by muse, mutect2, varscan2
- PCDHB5 | c.2109G>A p.S703= | Silent (SNP) | VAF 77/123 reads (63%) | catalogued as rs1326631392, COSV50647444; called by muse, mutect2, varscan2
- PHLDB2 | c.2145G>A p.L715= (on ENST00000393925 / NM_001134439.2; = p.L672= on NM_145753.2) | Silent (SNP) | VAF 49/119 reads (41%) | catalogued as COSV101208592, COSV67308424; called by muse, mutect2, varscan2
- PLXNB2 | c.126C>G p.A42= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV63780213; called by muse, mutect2, varscan2
- PRKCH | c.867G>A p.A289= | Silent (SNP) | VAF 35/122 reads (29%) | catalogued as rs1024065736, COSV60645918; called by muse, mutect2, varscan2
- PTK2B | c.1467G>A p.L489= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV57750333; called by muse, mutect2, varscan2
- RNF215 | c.807C>T p.L269= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs200160181; called by muse, mutect2, varscan2
- RPAP1 | c.1353G>A p.L451= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as COSV58537259; called by muse, mutect2, varscan2
- SEMA7A | c.1179C>T p.P393= | Silent (SNP) | VAF 41/108 reads (38%) | catalogued as rs1567071485, COSV56089403; called by muse, mutect2, varscan2
- SLC12A2 | c.2043C>T p.F681= | Silent (SNP) | VAF 37/64 reads (58%) | catalogued as rs1193145229, COSV52468593; called by muse, mutect2, varscan2
- SLC17A4 | c.1215C>T p.I405= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as COSV64955701; called by muse, varscan2
- SLC1A4 | c.858C>T p.D286= | Silent (SNP) | VAF 44/114 reads (39%) | catalogued as rs1324405266, COSV52233629; called by muse, mutect2, varscan2
- SLC30A8 | c.93G>A p.P31= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs751667454, COSV69968152, COSV69973921; called by muse, mutect2, varscan2
- SNX8 | c.1191G>A p.L397= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV56125250; called by muse, mutect2, varscan2
- SPHKAP | c.2505G>A p.L835= | Silent (SNP) | VAF 167/510 reads (33%) | catalogued as COSV60869453; called by muse, mutect2
- SPHKAP | c.2418G>A p.K806= | Silent (SNP) | VAF 123/320 reads (38%) | catalogued as COSV60869467; called by muse, mutect2, varscan2
- TPR | c.6240A>G p.P2080= | Silent (SNP) | VAF 148/241 reads (61%) | catalogued as rs1196739442, COSV66599571; called by muse, mutect2, varscan2
- TRAK1 | c.108C>T p.T36= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs35816590; called by muse, mutect2, varscan2
- TSBP1 | c.1212G>A p.Q404= (on ENST00000617061; = p.Q409= on NM_006781.5) | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as COSV66657743; called by muse, mutect2, varscan2
- VPS33A | c.873T>C p.S291= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV57356157; called by muse, mutect2, varscan2
- ZNF92 | c.294G>C p.V98= (on ENST00000328747 / NM_152626.4; = p.V29= on NM_007139.4) | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as COSV60873091, COSV60874945; called by muse, mutect2, varscan2
- ZSWIM5 | c.540C>T p.F180= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV100655904; called by muse, mutect2
- AP000769.3 | chr11:65504516 G>C | 5'Flank (SNP) | VAF 7/33 reads (21%) | catalogued as rs765004498; called by muse, mutect2, varscan2
- ARFRP1 | c.264+711C>G | Intron (SNP) | VAF 35/109 reads (32%) | catalogued as COSV53926419; called by muse, mutect2, varscan2
- DHRS4L1 | n.177-527C>T | Intron (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2
- DPF3 | c.871+2924G>A | Intron (SNP) | VAF 24/59 reads (41%) | catalogued as COSV63498902; called by muse, mutect2, varscan2
- FAM174C | c.*282C>T | 3'UTR (SNP) | VAF 32/96 reads (33%) | catalogued as rs368338725; called by muse, mutect2, varscan2
- MAP2 | c.5074-2099A>C | Intron (SNP) | VAF 18/58 reads (31%) | catalogued as COSV52282196; called by muse, mutect2, varscan2
- MIR520B | n.50C>T | RNA (SNP) | VAF 27/80 reads (34%) | called by muse, mutect2, varscan2
- PIK3CD | c.-138+2607G>C | Intron (SNP) | VAF 12/42 reads (29%) | catalogued as COSV66098622; called by muse, mutect2, varscan2
- ROPN1L | c.-1G>C | 5'UTR (SNP) | VAF 25/61 reads (41%) | catalogued as COSV56873516; called by muse, mutect2, varscan2
- TMBIM6 | c.-31+540T>A | Intron (SNP) | VAF 5/18 reads (28%) | catalogued as rs1333578925, COSV99920883; called by muse, mutect2, varscan2
